FM case AD5712 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/e35d2ef6-94dd-411d-abda-a19ac4f3370f

Male, 76.9 years: Mesothelioma, NOS (ICD-O-3 9050/3) of the pleura; metastasis biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
